Surgical pathology report (de-identified scan), TCGA case TCGA-IN-AB1V, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-AB1V-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Gastroesophageal junction
C16.0

JA 4/25/14

Anonymous number:

Accession Date:

Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODE, LEVEL 9, BIOPSY -

THREE LYMPH NODE FRAGMENTS, NEGATIVE FOR CARCINOMA (0/3).

PART 2: PARAESOPHAGEAL HERNIA NEAR LEFT MAINSTEM BRONCHUS, BIOPSY -

ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

PART 3: LYMPH NODE, PARAESOPHAGEAL NEAR RIGHT MAINSTEM BRONCHUS, BIOPSY -

LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

PART 4: LYMPH NODE, PARAESOPHAGEAL NEAR AZYGOUS, BIOPSY -

THREE LYMPH NODE FRAGMENTS, NEGATIVE FOR CARCINOMA (0/3).

PART 5: LYMPH NODE, NEAR RIGHT VAGUS, BIOPSY -

ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

PART 6: ESOPHAGUS AND PROXIMAL STOMACH, ESOPHAGOGASTRECTOMY -

A. MODERATELY DIFFERENTIATED ADENOCARCINOMA OF THE ESOPHAGOGASTRIC JUNCTION, 2.2 CM, INVADING INTO THE SUBMUCOSA AND ASSOCIATED WITH BARRETT'S MUCOSA.

B. NEGATIVE FOR ANGIOLYMPHATIC INVASION.

C. ALL SURGICAL MARGINS UNINVOLVED (PROXIMAL, DISTAL AND CIRCUMFERENTIAL ADVENTITIA).

D. ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

E. PATHOLOGIC STAGE: pT1b N0.

PART 7: LYMPH NODE, PERIGASTRIC, BIOPSY -

ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

PART 8: LYMPH NODE, SUBCARINAL NEAR TRACHEA, BIOPSY -

ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

PART 9: LYMPH NODE, SUBCARINAL ON ESOPHAGUS, BIOPSY -

ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

PART 10: LYMPH NODE, FAT PAD, BIOPSY -

ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

PART 11: GASTROESOPHAGEAL FAT, EXCISION -

TWENTY-FOUR LYMPH NODES, NEGATIVE FOR CARCINOMA (0/24).

PART 12: LYMPH NODE, SUBCARINAL, AZYGOUS, BIOPSY -

ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

[page 2 of 2]
FINAL DIAGNOSIS:

Collection Date:

- PART 1: LYMPH NODE, LEVEL 9, BIOPSY -
THREE LYMPH NODE FRAGMENTS, NEGATIVE FOR CARCINOMA (0/3).
- PART 2: PARAESOPHAGEAL HERNIA NEAR LEFT MAINSTEM BRONCHUS, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- PART 3: LYMPH NODE, PARAESOPHAGEAL NEAR RIGHT MAINSTEM BRONCHUS, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- PART 4: LYMPH NODE, PARAESOPHAGEAL NEAR AZYGUS, BIOPSY -
THREE LYMPH NODE FRAGMENTS, NEGATIVE FOR CARCINOMA (0/3).
- PART 5: LYMPH NODE, NEAR RIGHT VAGUS, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- PART 6: ESOPHAGUS AND PROXIMAL STOMACH, ESOPHAGOGASTRECTOMY -
A. MODERATELY DIFFERENTIATED ADENOCARCINOMA OF THE ESOPHAGOGASTRIC JUNCTION, 2.2 CM,
INVADING INTO THE SUBMUCOSA AND ASSOCIATED WITH BARRETT'S MUCOSA.
B. NEGATIVE FOR ANGIOLYMPHATIC INVASION.
C. ALL SURGICAL MARGINS UNINVOLVED (PROXIMAL, DISTAL AND CIRCUMFERENTIAL ADVENTITIA).
D. ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
E. PATHOLOGIC STAGE: pT1b N0.
- PART 7: LYMPH NODE, PERIGASTRIC, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- PART 8: LYMPH NODE, SUBCARINAL NEAR TRACHEA, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- PART 9: LYMPH NODE, SUBCARINAL ON ESOPHAGUS, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- PART 10: LYMPH NODE, FAT PAD, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- PART 11: GASTROESOPHAGEAL FAT, EXCISION -
TWENTY-FOUR LYMPH NODES, NEGATIVE FOR CARCINOMA (0/24).
- PART 12: LYMPH NODE, SUBCARINAL, AZYGUS, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- PART 13: STOMACH, GASTRECTOMY -
SEGMENT OF STOMACH WITHOUT SIGNIFICANT ABNORMALITY.
- PART 14: ANASTOMOTIC RINGS, RESECTION -
SEGMENTS OF STOMACH AND ESOPHAGUS WITHOUT SIGNIFICANT ABNORMALITY.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS

MACROSCOPIC

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Tumor midpoint centered on esophagogastric junction
TUMOR SIZE: Greatest dimension: 2.2 cm

MICROSCOPIC

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G2
PATHOLOGIC STAGING (pTNM)

pT1b
pN0
Number of lymph nodes examined: 39
Number of lymph nodes involved: 0
17 or more regional lymph nodes were identified
pM Not applicable
No prior treatment

PRIOR TREATMENT:
MARGINS

Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 13 mm
Specify margin: Circumferential adventitial margin

ANGIOLYMPHATIC INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS:

Intestinal metaplasia (Barrett's esophagus)

New copy of path report -
Resigned 11/20/14

Source: NCI Genomic Data Commons file 5ca7d04a-c264-4bcd-9ca2-6c0bf0659791 (TCGA-IN-AB1V.388833EE-F0C7-4B1C-8E98-31F4AAF90AE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).